Somatic mutation profile of tumor specimen TCGA-KL-8344-01A (aliquot TCGA-KL-8344-01A-11D-2310-10) from TCGA case TCGA-KL-8344, project TCGA-KICH (Kidney Chromophobe). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 51.3 years (18,742 days).
Specimen TCGA-KL-8344-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b2a322cf-caee-4abf-8fc3-084ed9842648.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KL-8344-11A (Solid Tissue Normal), aliquot TCGA-KL-8344-11A-01D-2310-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fef9b632-9994-4e3f-a6fc-cceefd6f4713

The open-access MAF lists 16 somatic variants for this specimen: 9 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 6, Splice Region 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DICER1 | c.1908A>G p.R636= | Splice Region (SNP) | VAF 37/67 reads (55%) | catalogued as rs1060503647, COSV58622363; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR11H12 | c.211C>A p.H71N | Missense Mutation (SNP) | VAF 112/295 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV101612505; called by muse, mutect2, varscan2
- ACTR8 | c.170C>A p.T57N | Missense Mutation (SNP) | VAF 85/202 reads (42%) | SIFT tolerated (0.39); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KIAA1109 | c.4009G>A p.V1337I | Missense Mutation (SNP) | VAF 77/248 reads (31%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- NOSIP | c.656A>G p.E219G | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.42); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- NXPE3 | c.1443C>G p.I481M | Missense Mutation (SNP) | VAF 63/137 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- OPRD1 | c.818G>A p.C273Y | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RC3H2 | c.3104T>C p.L1035P | Missense Mutation (SNP) | VAF 44/133 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SESN1 | c.923G>T p.S308I (on ENST00000356644 / NM_001199933.1; = p.S367I on NM_014454.3) | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- CFAP251 | c.2712C>T p.C904= | Silent (SNP) | VAF 29/81 reads (36%) | catalogued as COSV56609397; called by muse, mutect2, varscan2
- CUX2 | c.972G>T p.L324= | Silent (SNP) | VAF 3/46 reads (7%) | called by muse, mutect2
- MGA | c.4737A>G p.T1579= | Silent (SNP) | VAF 35/92 reads (38%) | called by muse, mutect2, varscan2
- PDPR | c.246C>T p.T82= | Silent (SNP) | VAF 67/490 reads (14%) | catalogued as COSV99848502; called by muse, varscan2
- SYT4 | c.1197A>G p.G399= | Silent (SNP) | VAF 24/210 reads (11%) | called by muse, mutect2, varscan2
- TTC19 | c.1077C>T p.H359= | Silent (SNP) | VAF 43/134 reads (32%) | catalogued as rs1272953061; called by muse, mutect2, varscan2
- NDUFV2 | c.-2C>T | 5'UTR (SNP) | VAF 15/33 reads (45%) | catalogued as rs528658653, COSV100571724; called by muse, mutect2, varscan2
